Surgical pathology report (de-identified scan), TCGA case TCGA-D6-A6EP, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-A6EP-01A (Primary Tumor).

Department of Cancer Pathology

Patient: XXX

Age:

Gender: M

Examination result No.

Unit in charge: Surgery and Laryngological Oncology Dept.

Physician in charge:

Clinical diagnosis (suspicion) Cancer of the larynx and lower pharynx

Date of admission:

Material:

1) Material: larynx. Please examine the marked margin. Method of collection: Collection of specimens for laboratory examination

Histopathological diagnosis

Examination performed on:

Invasive non-keratinising squamous cell carcinoma (G3).

Excision line involved. (8070/3 T-24100)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Tumour sized: 6 x 3.7 x 2.5 cm, whitish, lobular in the cross section

Assistant:

Pathologist:

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-O-3

Carcinoma, squamous cell
non-keratinising 8072/3
Site Hypopharynx NOS C12.9
JED 5/24/13

Diagnostic Discrepancy		✓
Pre or Malignancy History		✓
Case is (re)classified		

Source: NCI Genomic Data Commons file cec32e5e-ecb3-4dd0-ae10-251e5aae65e7 (TCGA-D6-A6EP.3B2DAD3C-8B0D-4542-9AEA-BDF27FA3E697.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).